Somatic mutation profile of tumor specimen MMRF_2207_1_BM_CD138pos (aliquot MMRF_2207_1_BM_CD138pos_T1_KHS5U_L11061) from MMRF case MMRF_2207, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,891 days).
Specimen MMRF_2207_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db143a0-cf46-421a-b583-eb30a8aa35d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2207_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2207_1_PB_Whole_C2_KHS5U_L08778; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6c3ae8d-2b67-403e-abaf-fa9afd8ddc75

The open-access MAF lists 78 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 10, Intron 6, 5'Flank 3, 3'Flank 3, In Frame Del 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP1 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779817458, COSV56257006; called by muse, mutect2, varscan2
- ANKRD50 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs774438602; called by muse, mutect2, varscan2
- CNTNAP4 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs750352753; called by muse, mutect2, varscan2
- FAT3 | c.8505A>C p.Q2835H | Missense Mutation (SNP) | VAF 124/212 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969150; called by muse, mutect2, varscan2
- FBRS | c.1222C>T p.R408C (on ENST00000287468; = p.R928C on NM_001105079.3) | Missense Mutation (SNP) | VAF 151/280 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs141695496; called by muse, mutect2, varscan2
- GNPDA2 | c.653_655del p.E218del | In Frame Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs778635504; called by pindel, varscan2
- IGHJ3 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 41/41 reads (100%) | PolyPhen benign (0.007); catalogued as rs185836312; called by muse, varscan2
- IGHV4-34 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs747062299; called by muse, mutect2, varscan2
- IGLV4-60 | c.295A>G p.T99A | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs373961102; called by muse, varscan2
- LRRC4C | c.551G>T p.R184I | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV99537208; called by muse, mutect2
- LRRIQ3 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs148456904, COSV104417055, COSV63050426; called by muse, mutect2, varscan2
- LSM2 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV65150366; called by muse, mutect2, varscan2
- NACAD | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71989564; called by muse, mutect2, varscan2
- OR10H4 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV100437677; called by muse, mutect2, varscan2
- PEX10 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs1484188014, COSV56580967; called by muse, mutect2, varscan2
- PSD | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 156/173 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV50054672; called by muse, mutect2, varscan2
- TBC1D13 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1253965765; called by muse, mutect2
- TLDC2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.614); catalogued as rs376888585; called by muse, mutect2, varscan2
- ADGRF5 | c.3469A>G p.T1157A | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); called by muse, mutect2
- AL592490.1 | c.1110A>T p.L370F | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- C11orf49 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- DIS3L2 | c.886_889del p.Y296Pfs*41 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- IFFO1 | c.1100A>T p.E367V (on ENST00000396840 / NM_001330324.2; = p.E370V on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); called by muse, mutect2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- IGHV4-34 | c.253_258del p.Y85_N86del | In Frame Del (DEL) | VAF 40/45 reads (89%) | called by pindel, varscan2
- IGLV6-57 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, varscan2
- NOP9 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIM1 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RIPOR2 | c.3043A>T p.T1015S | Missense Mutation (SNP) | VAF 127/197 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNASE12 | c.109A>C p.N37H | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- RPS3A | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SARM1 | c.1487C>A p.P496Q | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A4 | c.1373C>T p.A458V (on ENST00000264485 / NM_001098484.3; = p.A414V on NM_003759.4) | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL4A3 | c.1731A>G p.K577= | Silent (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- GJA10 | c.1530G>T p.V510= | Silent (SNP) | VAF 63/285 reads (22%) | catalogued as rs1484300114; called by muse, mutect2, varscan2
- HSPB8 | c.261C>T p.T87= | Silent (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.306C>T p.N102= | Silent (SNP) | VAF 28/31 reads (90%) | catalogued as rs371938225; called by muse, varscan2
- IGLV3-1 | c.78A>T p.P26= | Silent (SNP) | VAF 60/62 reads (97%) | catalogued as rs570281801; called by muse, varscan2
- IL17REL | c.246G>A p.A82= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs781249708, COSV100377335; called by muse, mutect2, varscan2
- MPDZ | c.3675G>C p.V1225= | Silent (SNP) | VAF 73/145 reads (50%) | called by muse, mutect2, varscan2
- RAB4A | c.255C>T p.G85= | Silent (SNP) | VAF 90/191 reads (47%) | catalogued as rs754560101; called by muse, mutect2, varscan2
- SKIV2L | c.1152C>A p.T384= | Silent (SNP) | VAF 129/213 reads (61%) | called by muse, mutect2, varscan2
- SLC16A1 | c.1029T>C p.C343= | Silent (SNP) | VAF 87/181 reads (48%) | called by muse, mutect2, varscan2
- AAAS | c.1331+49G>C | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- ABR | c.*1099G>T | 3'UTR (SNP) | VAF 127/304 reads (42%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*1687A>C | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- CGNL1 | c.*2771G>A | 3'UTR (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- CNTN5 | c.1580+35A>C | Intron (SNP) | VAF 56/83 reads (67%) | called by muse, mutect2
- DENND4C | chr9:19373484 G>C | 3'Flank (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- FMNL2 | c.2946+122T>C | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- GABRA4 | c.*4447A>T | 3'UTR (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- GAR1 | c.*269T>A | 3'UTR (SNP) | VAF 13/16 reads (81%) | called by muse, varscan2
- GLRA3 | c.*4311dup | 3'UTR (INS) | VAF 20/46 reads (43%) | catalogued as rs1377276291; called by mutect2, varscan2
- GRM1 | c.*2031C>T | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- H3C10 | c.*70T>A | 3'UTR (SNP) | VAF 8/218 reads (4%) | catalogued as rs890285283; called by muse, mutect2
- H3C10 | c.*71C>T | 3'UTR (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- HECTD1 | c.4982-41C>T | Intron (SNP) | VAF 68/121 reads (56%) | called by muse, mutect2, varscan2
- HIVEP3 | c.*2900C>T | 3'UTR (SNP) | VAF 75/194 reads (39%) | catalogued as rs1213349534; called by muse, mutect2, varscan2
- JMJD6 | chr17:76715177 C>T | 3'Flank (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- JUN | c.*870A>G | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- LIN28B | c.*2172del | 3'UTR (DEL) | VAF 30/94 reads (32%) | catalogued as rs573512821; called by mutect2, varscan2
- MEG3 | n.1186C>T | RNA (SNP) | VAF 8/198 reads (4%) | catalogued as rs1269659636; called by muse, mutect2
- MIR5195 | chr14:106851176 G>A | 5'Flank (SNP) | VAF 9/179 reads (5%) | catalogued as rs544903906; called by muse, mutect2
- NEMF | c.*1067C>T | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- NONO | c.1028+176T>C | Intron (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
- PCDH7 | chr4:30720289 G>T | 5'Flank (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2
- PGR | c.*8759T>G | 3'UTR (SNP) | VAF 21/67 reads (31%) | catalogued as COSV57662823; called by muse, mutect2, varscan2
- PGR | c.*6496A>C | 3'UTR (SNP) | VAF 39/215 reads (18%) | called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64745303 G>A | 3'Flank (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*4066_*4078del | 3'UTR (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- PXYLP1 | c.*737T>C | 3'UTR (SNP) | VAF 51/88 reads (58%) | called by muse, mutect2, varscan2
- RPS15A | c.*1097G>T | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by mutect2, varscan2
- SEC22C | c.*4078G>C | 3'UTR (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- SLIT3 | c.*1438C>T | 3'UTR (SNP) | VAF 33/118 reads (28%) | catalogued as rs971248191; called by muse, mutect2, varscan2
- SPHKAP | c.4959+79C>A | Intron (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- TBX3 | chr12:114683974 A>T | 5'Flank (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- VXN | c.*1446T>C | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.*2530A>C | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
